Somatic mutation profile of tumor specimen ALCH-B2NF-TTP1-A (aliquot ALCH-B2NF-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2NF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,533 days).
Specimen ALCH-B2NF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 648fcc74-c7f0-43fd-8c9c-c2cda3953d4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NF-NB1-A (Blood Derived Normal), aliquot ALCH-B2NF-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ece274f1-76c0-45eb-a796-2b2e20f716d6

The open-access MAF lists 216 somatic variants for this specimen: 135 protein-altering or splice-affecting, 54 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 54, Intron 14, Nonsense Mutation 10, Splice Region 5, RNA 4, Splice Site 3, Frame Shift Del 3, 5'UTR 3, 3'UTR 3, 5'Flank 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.11048-1G>A p.X3683_splice | Splice Site (SNP) | VAF 16/208 reads (8%) | catalogued as rs111033414; ClinVar: pathogenic; called by muse, mutect2
- ADGRG1 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1442408420; called by muse, mutect2
- CDH23 | c.2869C>G p.R957G | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV54940508; called by muse, mutect2
- CDH9 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV50250781; called by muse, mutect2
- CELF4 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1341658820, COSV58454371; called by muse, mutect2
- CSMD1 | c.690C>G p.N230K | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101215623; called by muse, mutect2
- DCSTAMP | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV52576267, COSV99034292; called by muse, varscan2
- DTD1 | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV66281712; called by muse, mutect2
- FAM71B | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1456591025; called by muse, mutect2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2
- FOXL2 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1285626047; called by muse, mutect2
- FPR2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs762976630, COSV100389141; called by muse, mutect2, varscan2
- H1-5 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV58901024; called by muse, mutect2, varscan2
- IGHV1-24 | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1555470261; called by muse, mutect2
- ITGAD | c.2681G>A p.R894K | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1282922684; called by muse, mutect2, varscan2
- ITGAM | c.240C>A p.V80= | Splice Region (SNP) | VAF 10/172 reads (6%) | catalogued as rs1305310793, COSV54934827, COSV54934970; called by muse, mutect2
- KATNIP | c.2882A>T p.D961V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55174004; called by muse, mutect2, varscan2
- KPRP | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.359); catalogued as COSV64220960; called by muse, mutect2, varscan2
- KRT2 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 29/548 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.949); catalogued as COSV59012919; called by muse, mutect2
- LAG3 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.97); catalogued as COSV52566308; called by muse, mutect2
- LAMA2 | c.5552C>A p.S1851Y | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs758098650, COSV101370623; called by muse, mutect2, varscan2
- LRP1B | c.11659G>C p.D3887H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); catalogued as COSV67257542; called by muse, mutect2
- MARCHF9 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 130/307 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs369104296; called by muse, mutect2, varscan2
- MKNK1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57862266, COSV57862498; called by muse, mutect2
- MVP | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs148167046, COSV62422332; called by muse, mutect2, varscan2
- MYH8 | c.4399C>G p.Q1467E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV67964587; called by muse, mutect2, varscan2
- NANP | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV59159920; called by muse, mutect2, varscan2
- NAT16 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs772322657, COSV100296266; called by muse, mutect2, varscan2
- NDRG1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.734); catalogued as COSV60482957; called by muse, mutect2, varscan2
- NELFB | c.930C>T p.F310= | Splice Region (SNP) | VAF 19/211 reads (9%) | catalogued as rs761641101; called by muse, mutect2
- NLRP4 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs777046355, COSV100016030; called by muse, mutect2, varscan2
- NPAS3 | c.2180G>T p.R727L (on ENST00000356141 / NM_001164749.2; = p.R695L on NM_022123.3) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs1406731636; called by muse, mutect2
- NRXN2 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55463313, COSV99633204; called by muse, mutect2
- OR6N2 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59412292; called by muse, mutect2, varscan2
- OTOG | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV68037362; called by muse, mutect2
- OTUD7A | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1377808017; called by muse, mutect2
- RAET1G | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1452430600; called by muse, mutect2
- RGPD3 | c.4282G>T p.V1428L | Missense Mutation (SNP) | VAF 20/818 reads (2%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs758369847; called by muse, mutect2
- SCN4A | c.4390G>A p.G1464R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs150423825, COSV101438308, COSV71126675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULF1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV52678056; called by muse, mutect2
- SYT13 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV50073945; called by muse, mutect2
- TAOK3 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs368702140; called by muse, mutect2, varscan2
- TH | c.738-5C>A | Splice Region (SNP) | VAF 12/172 reads (7%) | catalogued as rs1162333864; called by muse, mutect2
- VWC2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100514428; called by muse, mutect2
- WDFY3 | c.8041G>T p.G2681* | Nonsense Mutation (SNP) | VAF 17/145 reads (12%) | catalogued as COSV55695917; called by muse, mutect2, varscan2
- ZNF322 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 22/366 reads (6%) | catalogued as COSV70652281; called by muse, mutect2
- ZNF586 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs762279144; called by muse, mutect2, varscan2
- ABCA9 | c.2092G>C p.G698R | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC009533.1 | n.581G>T | Splice Region (SNP) | VAF 73/760 reads (10%) | called by muse, mutect2
- ACTR3 | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.834); called by muse, mutect2
- ADAMTS16 | c.2408T>C p.V803A | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRB1 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGAP5 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 70/565 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGXT2 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ALKAL2 | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 30/296 reads (10%) | called by muse, mutect2
- APOB | c.3816C>A p.H1272Q | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- AQR | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ARHGEF6 | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATE1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.035); called by muse, mutect2
- C12orf56 | c.1509+4C>A | Splice Region (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2
- C8B | c.1342C>A p.L448M | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- C9orf131 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2
- CACNA1A | c.5089C>A p.L1697M | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAMK2D | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CEP128 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CMTR2 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1937del p.N646Ifs*53 | Frame Shift Del (DEL) | VAF 9/112 reads (8%) | called by pindel, varscan2*
- CNTNAP5 | c.2283G>C p.Q761H | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COBLL1 | c.63G>T p.Q21H (on ENST00000392717; = p.Q29H on NM_001278458.2) | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL6A3 | c.6954C>A p.Y2318* | Nonsense Mutation (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- COL6A5 | c.3901del p.R1301Gfs*18 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | called by mutect2, pindel
- DENND5B | c.2067G>T p.Q689H | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2
- DGKA | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- DSG4 | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM161B | c.2002G>T p.E668* (on ENST00000651776; = p.E605* on NM_152445.3) | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- FAM216B | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GAPVD1 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.353); called by muse, mutect2
- GFI1 | c.1065G>C p.M355I | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GIGYF2 | c.1083A>C p.R361S | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- GLS | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRB7 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.045); called by muse, mutect2
- GRXCR2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GTF2H1 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HBG2 | c.359dup p.K121Qfs*6 | Frame Shift Ins (INS) | VAF 42/275 reads (15%) | called by mutect2, varscan2
- HERC2 | c.6046G>A p.V2016M | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- HJURP | c.1294A>T p.R432W | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HNRNPK | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HOXD13 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.554); called by muse, mutect2
- HUWE1 | c.11174G>A p.R3725K | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KATNIP | c.4044G>T p.K1348N | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIF5A | c.3015C>A p.D1005E | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- KMT2D | c.15692C>T p.S5231F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KRTAP10-1 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 57/849 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- LDHD | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIX1 | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEB6B | c.259A>T p.M87L | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- MEGF10 | c.324C>A p.H108Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.449); called by muse, mutect2
- MFSD2A | c.1618G>T p.A540S (on ENST00000372809 / NM_001136493.3; = p.A527S on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.492); called by muse, mutect2
- MRGPRF | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MS4A12 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- MYH7 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MYO10 | c.3202A>G p.S1068G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); called by muse, mutect2
- NDRG3 | c.452A>T p.H151L (on ENST00000349004 / NM_032013.4; = p.H139L on NM_022477.4) | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NEXMIF | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2
- NFATC2IP | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- NLRP14 | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPHS2 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- OR51A4 | c.170T>A p.L57* | Nonsense Mutation (SNP) | VAF 20/317 reads (6%) | called by muse, mutect2
- ORM2 | c.415A>T p.N139Y | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OTX2 | c.781G>C p.D261H (on ENST00000408990 / NM_172337.3; = p.D269H on NM_021728.4) | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PAPSS1 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2
- PDILT | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLCB1 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, varscan2
- PRPF8 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.297); called by muse, mutect2
- PRR12 | c.404G>C p.G135A (on ENST00000615927; = p.G956A on NM_020719.3) | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- PSMD12 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- RIMS2 | c.3625C>A p.L1209M | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- S100A2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2
- SECISBP2L | c.2461del p.M821Wfs*14 (on ENST00000559471 / NM_001193489.2; = p.M776Wfs*14 on NM_014701.4) | Frame Shift Del (DEL) | VAF 30/284 reads (11%) | called by mutect2, varscan2
- SETD3 | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.049); called by muse, mutect2
- SLC39A12 | c.633G>C p.M211I | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- SLIT1 | c.3619G>A p.G1207R | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA21 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SPIN2A | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- ST13 | c.383-1G>T p.X128_splice | Splice Site (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- ST8SIA6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5 | c.2494C>T p.P832S (on ENST00000321680 / NM_001127715.2; = p.P796S on NM_139244.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2
- STXBP5L | c.2460T>A p.S820R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TAFA3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/151 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- UACA | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- UGT3A1 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UNC5D | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.8414G>C p.G2805A | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZKSCAN8 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF528 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, varscan2
- ACKR3 | c.141C>A p.L47= | Silent (SNP) | VAF 24/349 reads (7%) | called by muse, mutect2
- ADAM22 | c.936T>C p.F312= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as COSV99717238; called by muse, mutect2
- ADCY8 | c.3588C>G p.V1196= | Silent (SNP) | VAF 37/183 reads (20%) | called by muse, mutect2, varscan2
- ADGRG1 | c.993C>T p.L331= | Silent (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- ADGRG1 | c.1359C>T p.V453= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- ADGRG7 | c.702T>A p.L234= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- AMER3 | c.336G>C p.V112= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100366736; called by muse, mutect2
- ATP2B3 | c.1527C>A p.L509= | Silent (SNP) | VAF 46/349 reads (13%) | called by muse, mutect2, varscan2
- CCNI | c.288C>T p.F96= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- CDH11 | c.1329A>G p.T443= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- CLEC12A | c.627C>T p.I209= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as rs752486060; called by muse, mutect2
- CPLANE1 | c.8040G>T p.L2680= | Silent (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- DIDO1 | c.4896C>T p.D1632= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV56622458; called by muse, mutect2
- DNAH5 | c.10743G>T p.L3581= | Silent (SNP) | VAF 30/273 reads (11%) | called by muse, mutect2, varscan2
- DRC7 | c.1723C>T p.L575= | Silent (SNP) | VAF 19/211 reads (9%) | called by muse, mutect2
- FAT4 | c.1648C>T p.L550= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV67898657, COSV67902972; called by muse, mutect2
- FKBP7 | c.225G>T p.R75= | Silent (SNP) | VAF 17/173 reads (10%) | called by muse, mutect2
- GPR174 | c.165G>C p.V55= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- HOXB1 | c.51G>T p.R17= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- IQGAP3 | c.4261C>A p.R1421= | Silent (SNP) | VAF 36/500 reads (7%) | called by muse, mutect2
- IRS1 | c.1023G>T p.S341= | Silent (SNP) | VAF 10/108 reads (9%) | called by mutect2, varscan2
- KCNA2 | c.315C>T p.P105= | Silent (SNP) | VAF 12/337 reads (4%) | called by muse, mutect2
- MAFB | c.330G>A p.A110= | Silent (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- MAGEB6B | c.258C>A p.A86= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- MAN2A1 | c.81C>T p.D27= | Silent (SNP) | VAF 57/443 reads (13%) | called by muse, mutect2, varscan2
- MFSD9 | c.1179G>T p.T393= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs201422340; called by muse, mutect2
- MPO | c.240G>A p.R80= | Silent (SNP) | VAF 30/484 reads (6%) | catalogued as COSV56568181; called by muse, mutect2
- NLRP12 | c.837C>G p.L279= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- NOS1AP | c.855A>T p.T285= | Silent (SNP) | VAF 30/435 reads (7%) | called by muse, mutect2
- OR2G2 | c.354G>T p.P118= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV60739763, COSV60740569; called by muse, mutect2, varscan2
- OR4C3 | c.588G>T p.L196= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- OR52A5 | c.585C>A p.I195= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs777752079, COSV100263555; called by muse, mutect2, varscan2
- PGR | c.1551C>T p.L517= | Silent (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- PIF1 | c.378G>T p.A126= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.2269C>T p.L757= | Silent (SNP) | VAF 46/711 reads (6%) | called by muse, mutect2
- POLQ | c.663G>T p.L221= | Silent (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- PRELP | c.459G>T p.V153= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- PRSS56 | c.1224G>A p.L408= | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- PYGB | c.309G>T p.L103= | Silent (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- SCART1 | c.468G>C p.V156= | Silent (SNP) | VAF 34/645 reads (5%) | called by muse, mutect2
- SIM1 | c.1479C>A p.R493= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs928670652, COSV53488921; called by muse, mutect2, varscan2
- SLC12A5 | c.1311C>T p.I437= (on ENST00000454036 / NM_001134771.2; = p.I414= on NM_020708.5) | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- SLITRK5 | c.1920G>T p.A640= | Silent (SNP) | VAF 9/234 reads (4%) | catalogued as COSV100281276; called by muse, mutect2
- SNAPC4 | c.3468C>G p.P1156= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- STAG3 | c.690C>A p.A230= | Silent (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2
- TCERG1L | c.885C>A p.A295= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- TIMP3 | c.310C>T p.L104= | Silent (SNP) | VAF 17/265 reads (6%) | called by muse, mutect2
- TMEM121B | c.1407G>T p.L469= | Silent (SNP) | VAF 18/271 reads (7%) | called by muse, mutect2
- TOR1AIP1 | c.1338G>C p.G446= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- TTN | c.21081C>T p.C7027= (on ENST00000591111; = p.C6100= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- TXNDC11 | c.2175C>T p.L725= (on ENST00000356957 / NM_001303447.2; = p.L698= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- UGT1A8 | c.633C>T p.I211= | Silent (SNP) | VAF 32/351 reads (9%) | called by muse, mutect2
- USP37 | c.1245A>T p.S415= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- ZNF804A | c.639C>A p.G213= | Silent (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- AC004696.1 | chr19:56495075 G>T | 5'Flank (SNP) | VAF 10/130 reads (8%) | catalogued as rs1385980985; called by muse, mutect2
- AC044798.1 | n.177T>C | RNA (SNP) | VAF 11/72 reads (15%) | called by muse, varscan2
- ACTN2 | c.1840-30C>G | Intron (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- AP000769.3 | chr11:65504415 G>C | 5'Flank (SNP) | VAF 13/135 reads (10%) | called by muse, varscan2
- APLP2 | c.-38G>C | 5'UTR (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- C10orf67 | c.206+606G>T | Intron (SNP) | VAF 12/194 reads (6%) | catalogued as rs1208407396; called by muse, mutect2
- FBXL7 | c.-26G>T | 5'UTR (SNP) | VAF 38/492 reads (8%) | called by muse, mutect2
- FOXD1 | c.*17C>A | 3'UTR (SNP) | VAF 35/392 reads (9%) | called by muse, mutect2
- GNA12 | c.526-29202C>T | Intron (SNP) | VAF 10/159 reads (6%) | catalogued as rs1178251642, COSV99282743; called by muse, mutect2
- KRTAP10-9 | c.*2G>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as rs376402427; called by muse, mutect2, varscan2
- LBHD1 | c.-1288C>G | 5'UTR (SNP) | VAF 10/130 reads (8%) | catalogued as rs1398053326; called by muse, mutect2
- LINC00452 | n.612-3474T>A | Intron (SNP) | VAF 17/238 reads (7%) | called by muse, mutect2
- LINC01511 | n.437-8404C>T | Intron (SNP) | VAF 12/352 reads (3%) | catalogued as rs868289849; called by muse, mutect2
- LRRC27 | chr10:132331446 C>T | 5'Flank (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- MARCHF1 | c.-322-85692G>T | Intron (SNP) | VAF 20/338 reads (6%) | catalogued as COSV72275335; called by muse, mutect2
- MSL3P1 | n.934C>T | RNA (SNP) | VAF 18/161 reads (11%) | catalogued as rs781586742; called by muse, mutect2, varscan2
- OR5AK4P | n.546C>T | RNA (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- PRAME | c.22-1781A>G | Intron (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- PRDM11 | c.657-6917G>T | Intron (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- PROCA1 | c.78+712T>A | Intron (SNP) | VAF 17/242 reads (7%) | called by muse, mutect2
- RNASE9 | c.-14-1407G>T | Intron (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- SGIP1 | c.1315+1795G>T | Intron (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- SNORD115-36 | n.68A>G | RNA (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- TG | c.176+18A>C | Intron (SNP) | VAF 56/298 reads (19%) | called by muse, mutect2
- TWF1 | c.25+589C>G | Intron (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- UBALD1 | c.184-215G>A | Intron (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- ZNF770 | c.*1698G>A | 3'UTR (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
